CGCI case HTMCP-01-16-00266 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d74d08c6-50fe-4d43-b8b1-524444e90494

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 41.8 years (15,261 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,174 days (3.2 years); Max tumor bulk site: Soft tissue (muscle, ligaments, subcutaneous); Sites of involvement: Soft tissue / Oropharynx.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary.
   Pathology details: Lymph node involved site: Mediastinal.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 243 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Frontal lobe; Days to progression: 243 days.
- Days to follow up: 928 days (2.5 years); Disease response: With Tumor.
- Days to follow up: 1,174 days (3.2 years); Disease response: With Tumor.
- Follow-up contacts recording only the day: day 0, day 477.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD30: Positive.
- CD5: Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Test: Negative; Specialized molecular test: EBER.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Haart treatment indicator: Yes.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Biospecimens (3 samples)
- Sample HTMCP-01-16-00266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-16-00266-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-16-00266-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- History of disease: Year of HIV diagnosis: 2008; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Oropharynx.
- Primary pathology: Method initial path diagnosis: Biopsy (all types).
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: Eber.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: Right Frontal Lobe (Brain); New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: Right Frontal Lobe(Brain); New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00266-01A-01E-13312:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00266-01A-01S-13312:
- % tumour top: 90
- % tumour bottom: 90
